Somatic mutation profile of tumor specimen TCGA-12-1599-01A (aliquot TCGA-12-1599-01A-01W-0643-08) from TCGA case TCGA-12-1599, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.7 years (17,432 days).
Specimen TCGA-12-1599-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83bf3d3f-bca8-4a00-857c-5d1c647de431.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1599-10A (Blood Derived Normal), aliquot TCGA-12-1599-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1efae7be-1c7a-40ea-a620-e7d2851b35ce

The open-access MAF lists 44 somatic variants for this specimen: 26 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 16, Intron 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BACH1 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs749628333, COSV99727809; called by muse, mutect2, varscan2
- CACNA1S | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs779029870, COSV62941137; called by muse, mutect2, varscan2
- CFTR | c.3743C>A p.S1248* | Nonsense Mutation (SNP) | VAF 67/310 reads (22%) | catalogued as CM160269, COSV50045584, COSV50083214; called by muse, mutect2, varscan2
- DNAH2 | c.6541G>A p.V2181I | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs147226714; called by muse, mutect2, varscan2
- DNAI3 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54005307, COSV99641202; called by muse, mutect2, varscan2
- FBP2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs554337531, COSV100942011, COSV64695070; called by muse, mutect2, varscan2
- FBP2 | c.529T>G p.S177A | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV100942015; called by muse, mutect2, varscan2
- GPR101 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as COSV99981200; called by muse, mutect2, varscan2
- IMPA1 | c.153A>C p.E51D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99808718; called by muse, mutect2, varscan2
- JARID2 | c.2527C>G p.P843A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100521084; called by muse, mutect2
- KEL | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs750806448, CM1314015, COSV100786806; called by muse, mutect2, varscan2
- MRGPRX1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as rs767184906, COSV57106940; called by muse, mutect2, varscan2
- MYO3A | c.2420A>T p.K807I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99777670, COSV99777842; called by muse, mutect2
- NF1 | c.4445T>C p.I1482T (on ENST00000358273 / NM_001042492.3; = p.I1461T on NM_000267.3) | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs746994734, COSV62208879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA2 | c.2738A>G p.Q913R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV100884898; called by muse, mutect2, varscan2
- PPP1R3A | c.2825C>G p.A942G | Missense Mutation (SNP) | VAF 118/466 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV99491688; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 78/198 reads (39%) | catalogued as rs146650273; called by pindel, varscan2
- PTPRH | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558110066, COSV54745822; called by muse, mutect2, varscan2
- RALGAPB | c.4208G>A p.R1403Q | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs761685356, COSV99484553; called by muse, mutect2, varscan2
- SLC6A15 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1173837286, COSV57023032; called by muse, mutect2, varscan2
- SLC9A2 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 97/254 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs758758483, COSV52134997; called by muse, mutect2, varscan2
- TG | c.6098A>T p.Q2033L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV99598416; called by muse, varscan2
- TMPRSS7 | c.857G>A p.R286H (on ENST00000452346; = p.R160H on NM_001042575.2) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs746041967, COSV69981748, COSV69982427; called by muse, mutect2, varscan2
- UBR4 | c.3823A>G p.S1275G | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100919937; called by muse, mutect2, varscan2
- ZC3H18 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.102); catalogued as COSV56326307; called by muse, mutect2, varscan2
- POTEA | c.1477G>T p.V493F (on ENST00000519951 / NM_001005365.2; = p.V447F on NM_001002920.1) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- C6orf89 | c.642C>T p.F214= (on ENST00000373685; = p.F221= on NM_152734.4) | Silent (SNP) | VAF 75/209 reads (36%) | catalogued as rs757039166, COSV100769656; called by muse, mutect2, varscan2
- CDCA2 | c.558C>T p.S186= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs758525945, COSV100398699; called by muse, mutect2, varscan2
- DSE | c.540G>A p.V180= | Silent (SNP) | VAF 71/245 reads (29%) | catalogued as COSV100528237; called by muse, mutect2, varscan2
- HELZ2 | c.7314G>A p.A2438= (on ENST00000467148 / NM_001037335.2; = p.A1869= on NM_033405.3) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs749696579, COSV64443224; called by muse, varscan2
- HMCN1 | c.11010C>A p.I3670= | Silent (SNP) | VAF 54/228 reads (24%) | catalogued as COSV99622478; called by muse, mutect2, varscan2
- IFFO1 | c.1167G>C p.G389= (on ENST00000396840 / NM_001330324.2; = p.G392= on NM_080730.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100350617; called by muse, mutect2, varscan2
- IL1R2 | c.180T>G p.S60= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs1406883126, COSV100207649; called by muse, mutect2, varscan2
- MAPK4 | c.361C>T p.L121= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV101244972; called by muse, mutect2, varscan2
- NLRP13 | c.1329C>T p.Y443= | Silent (SNP) | VAF 40/182 reads (22%) | catalogued as rs768162534, COSV61619711, COSV61622587; called by muse, mutect2, varscan2
- OR2A7 | c.210C>T p.I70= | Silent (SNP) | VAF 22/194 reads (11%) | catalogued as rs762987209, COSV71828503; called by muse, mutect2, varscan2
- PGR | c.2595G>A p.S865= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as rs747391838, COSV54810959; called by muse, mutect2, varscan2
- PTPRU | c.2520C>T p.S840= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs771530684, COSV100111241; called by muse, mutect2, varscan2
- SLC23A3 | c.1428C>A p.V476= (on ENST00000409878 / NM_001144889.2; = p.V359= on NM_144712.5) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1418767062, COSV99840758; called by mutect2, varscan2
- SPANXN2 | c.276T>A p.A92= | Silent (SNP) | VAF 726/2346 reads (31%) | catalogued as COSV100979745; called by muse, varscan2
- TPGS2 | c.771G>A p.K257= | Silent (SNP) | VAF 108/405 reads (27%) | catalogued as COSV100528691; called by muse, mutect2, varscan2
- TTC30B | c.999T>C p.Y333= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as COSV101282756; called by muse, mutect2, varscan2
- MIR548I2 | n.133G>A | RNA (SNP) | VAF 39/157 reads (25%) | catalogued as rs780852741; called by muse, mutect2, varscan2
- TTN | c.10360+2929G>A | Intron (SNP) | VAF 72/201 reads (36%) | catalogued as rs769428404, COSV59993112; called by muse, mutect2, varscan2
